Somatic mutation profile of tumor specimen TCGA-DH-A66D-01A (aliquot TCGA-DH-A66D-01A-11D-A31L-08) from TCGA case TCGA-DH-A66D, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.4 years (15,866 days).
Specimen TCGA-DH-A66D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fd9ba36-e335-468c-bece-11c5b1c10ea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A66D-10A (Blood Derived Normal), aliquot TCGA-DH-A66D-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b591959-bc65-4be1-a611-d38c5f71b8e9

The open-access MAF lists 44 somatic variants for this specimen: 41 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 35, Silent 3, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 65/84 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFTPH | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99481333; called by muse, mutect2, varscan2
- AL592490.1 | c.1160G>C p.G387A | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV101308308, COSV69425245; called by muse, mutect2
- AL592490.1 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV101308309, COSV69424828; called by muse, mutect2
- ALMS1 | c.3356A>C p.E1119A | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100044031; called by muse, mutect2, varscan2
- AMMECR1L | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs188584936, COSV99761593; called by muse, mutect2, varscan2
- ARHGAP6 | c.2414C>G p.P805R (on ENST00000337414 / NM_013427.3; = p.P602R on NM_013423.3) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); catalogued as COSV100273658; called by muse, mutect2
- ARSI | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs199878549, COSV60817229; called by muse, mutect2, varscan2
- ATP2A2 | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100428990; called by muse, mutect2, varscan2
- ATRX | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 43/84 reads (51%) | catalogued as COSV100971602, COSV64884503; called by muse, mutect2, varscan2
- B3GNT3 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100592882; called by muse, mutect2, varscan2
- CEP97 | c.1607A>T p.K536I | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV100512129; called by muse, mutect2, varscan2
- CYLC1 | c.1852T>G p.S618A | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.844); catalogued as COSV100255618; called by muse, mutect2, varscan2
- DOCK5 | c.3736A>G p.K1246E | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV52416423; called by muse, mutect2, varscan2
- FTSJ3 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100037496; called by muse, mutect2, varscan2
- FUT4 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as COSV100708216; called by muse, mutect2
- FZD8 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020278; called by muse, mutect2, varscan2
- GCNA | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 177/450 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV101032747; called by muse, varscan2
- GLRA3 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56860472; called by muse, mutect2, varscan2
- ING3 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59950998; called by muse, mutect2, varscan2
- LINGO2 | c.1227dup p.P410Tfs*5 | Frame Shift Ins (INS) | VAF 23/134 reads (17%) | catalogued as rs1358205090; called by mutect2, pindel, varscan2
- LRRC30 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 144/325 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274469; called by muse, mutect2, varscan2
- MCM3AP | c.5585C>T p.A1862V | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs772612320, COSV52442791; called by muse, mutect2, varscan2
- MED12 | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); catalogued as rs763700798, COSV61347042; called by muse, mutect2, varscan2
- MRPL51 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99975269; called by muse, mutect2
- NKX2-2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV65819634; called by muse, mutect2, varscan2
- PLAT | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1020857645, COSV54277868, COSV99535066; called by muse, mutect2, varscan2
- RNASEH1 | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1395841118, COSV100177310; called by muse, mutect2, varscan2
- ROBO1 | c.3148A>C p.M1050L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.048); catalogued as COSV101459552; called by muse, mutect2, varscan2
- SERAC1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs1335562972, COSV100894909; called by muse, mutect2, varscan2
- SLC10A7 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs755106015, COSV99391193; called by muse, mutect2, varscan2
- SRD5A3 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs758849298, COSV51713233; called by muse, mutect2, varscan2
- TBL3 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100225150; called by muse, mutect2, varscan2
- THOC2 | c.4033A>G p.T1345A | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1339252599, COSV99834407; called by muse, mutect2, varscan2
- TRIM55 | c.488_489del p.H163Rfs*8 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as rs777889021; called by mutect2, pindel, varscan2
- UBE4A | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99348709; called by muse, mutect2, varscan2
- VGLL2 | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV100410041; called by muse, mutect2
- MAGEB6B | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- NEO1 | c.854del p.N285Mfs*37 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- OPHN1 | c.2102C>A p.T701N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- CARD11 | c.1740C>T p.D580= | Silent (SNP) | VAF 70/134 reads (52%) | catalogued as rs775014401, COSV62756688; called by muse, mutect2, varscan2
- CASR | c.1524C>T p.C508= (on ENST00000490131; = p.C585= on NM_000388.4) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99949570; called by muse, varscan2
- IGF2BP1 | c.1707T>C p.S569= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99289203; called by muse, mutect2, varscan2
